Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3456, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3456-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right renal mass

Source of Specimen(s):

- 1: Right Kidney with Adrenals
- 2: Paracaval Lymph Nodes, Right
- 3: Hernia sac

Gross Description:

Received in three parts.

Source of Tissue: 1. Labeled # 1, "right kidney and adrenal"

Gross Description: Received fresh in a container labeled ", right kidney and adrenal". It consists of a 1,000-gram radical nephrectomy specimen consisting of a grossly enlarged distorted right kidney measuring 20.0 x 14.0 x 11.0 cm, perinephric fat ranging from 0.1 up to 4.0 cm and right adrenal gland measuring 4.5 x 3.2 x 1.0 cm. Sections through the adrenal gland disclose normal orange parenchyma. At the hilum, the segment of ureter measures 9.0 x 0.7 cm and is unremarkable. The ureter is opened and is free of lesions or masses. At the hilum, the fat has some fullness however no obvious lymph nodes are identified. The vascular margins are unremarkable. The kidney is sectioned disclosing a large variegated orangish yellow to reddish brown tumor comprising 98% of the kidney and measuring 17.0 x 13.0 x 10.0 cm. The tumor obliterates the calyceal system and comes to within 1.0 cm from the hilum. The small amount of uninvolved, normal appearing renal parenchyma is medial in the specimen. There are multiple areas where tumor is pushing on the capsule however, no obvious invasion through the capsule is found. A large amount of the tumor appears to be necrotic. Fresh tissue is procured for Cytogenetics. Representative sections are submitted in 1A-H.

Designation of Sections: 1A- adrenal gland, 1B- vascular and ureter margins, 1C-1D- tumor in relationship to hilum and renal pelvis, 1E-1F- potential viable tumor, 1G- tumor in relationship to capsule, 1H- perinephric fat overlying areas of tumor

Source of Tissue: 2. Labeled # 2, "paracaval right lymph nodes"

Gross Description: Received fresh in a container labeled ", paracaval right lymph nodes". It consists of a single elongated lymph node measuring 4.0 x 1.9 x 1.5 cm. Entirely submitted in 2A-C.

[page 2 of 4]
Source of Tissue: 3. Labeled # 3, "hernia sac"

Gross Description: Received fresh in a container labeled " hernia sac". It consists of a ragged fragment of fibromembranous fibroadipose tissue and some skeletal muscle measuring overall 12 x 5 x 2 cm. No suspicious areas are identified grossly. Representative sections are submitted in 3A.

Final Diagnosis:

***** AMENDED

REPORT*****

This report is amended to change the diagnosis.

1. Right kidney and adrenal gland, nephrectomy and adrenalectomy:- Renal cell carcinoma with Xp11.2 translocation, with necrosis, 17.0 cm in greatest dimension grossly.

- Lymphovascular invasion is not identified.
- Ureteral and vascular resection margins are free of tumor.
- Adrenal gland with focal cortical nodular hyperplasia.

Note: Immunohistochemical stains performed on block 1D show the tumor to be positive for vimentin and negative for CK7. The tumor is negative for mucicarmine special stain. These findings along with histomorphology support a clear cell carcinoma.

Note #2: This is a renal tumor with combined morphological features of clear cells and papillary architectural patterns. Clusters of histiocytes are seen as well. Cytogenetics study shows t(X;1)(p11.2;p34) translocation. Additional immunohistochemistry stains performed on block 1D show the tumor to be positive for RCC, CD10, whereas negative for pancytokeratin AE1/AE3, CAM5.2, K903 (34BE12), EMA, WT-1 and MITF. Case was discussed with [REDACTED]

2. Right paracaval lymph nodes, excision:- One lymph node, no tumor seen (0/1).

3. Hernia sac, resection:- Fibrovascular tissue and fibroadipose tissue, consistent with hernia sac.
- No tumor seen.

pTNM: T2 N0 Mx.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the [REDACTED]

[page 3 of 4]
Center. These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement [REDACTED] (CLIA) as qualified to perform high complexity clinical testing.

[REDACTED]
*****ORIGINAL

REPORT*****

1. Right kidney and adrenal gland, nephrectomy and adrenalectomy:- Renal cell carcinoma, clear cell type, with necrosis, 17.0 cm in greatest dimension grossly, confined to the kidney, [REDACTED] nuclear grade III/IV.

- Lymphovascular invasion is not identified.
- Ureteral and vascular resection margins are free of tumor.
- Adrenal gland with focal cortical nodular hyperplasia.

Note: Immunohistochemical stains performed on block 1D show the tumor to be positive for vimentin and negative for CK7. The tumor is negative for mucicarmine special stain. These findings along with histomorphology support a clear cell carcinoma.

2. Right paracaval lymph nodes, excision:- One lymph node, no tumor seen (0/1).

3. Hernia sac, resection:- Fibrovascular tissue and fibroadipose tissue, consistent with hernia sac.
- No tumor seen.

pTNM: T2 N0 Mx.

[REDACTED]
FC Cytogenetics Solid
Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Right Renal Mass

KARYOTYPE: Abnormal [REDACTED] karyotype: 46,Y,t(X;1)(p11.2;p34)[cp21]

RESULTS: The renal mass was harvested after seven and nine days in culture. The chromosomes from 21 metaphases were counted and analyzed,

[page 4 of 4]
and three of these metaphases were karyotyped by G-banding. The modal chromosome number was 46, and all the cells had a balanced translocation between the p arms of chromosomes X and 1. This translocation juxtaposed the TFE3 gene at Xp11.2 with the PSF gene at 1p34. The expression of the resulting fusion gene, PSF-TFE3, in renal epithelial cells has been reported to play a role in the development of renal cell carcinoma (please see the addendum to the Surgical Pathology Report).

Source: NCI Genomic Data Commons file 3366b6f7-98e2-46d5-90e6-60ea0f267cf1 (TCGA-AK-3456.1BA28891-0047-424F-917D-542A9CA90343.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).